TCGA case TCGA-ZG-A9M4 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: University Medical Center Hamburg-Eppendorf. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b5d36b2-8b46-48a4-afa7-0e1936f2d315

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 65.8 years (24,030 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; AJCC clinical T: T2a; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N1; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 18; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Overlapping/multiple zones.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 21 (initial diagnosis): Days to imaging: 21 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 22 (initial diagnosis): Days to imaging: 22 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: Extraprostatic Extension, Regional Lymphadenopathy.
- Days to follow up: 223 days; Disease response: With Tumor.
- Days to follow up: 547 days (1.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.95 ng/mL (day 218).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZG-A9M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-ZG-A9M4-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZG-A9M4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Treatment outcome first course: Partial Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Diagnostic ct abd pelvis results: Ct scan ab pelvis results: Extraprostatic Extension (regional lymphadenopathy)[e.g. cN1].
- Stage record, Psa: PSA most recent results: 0.95.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 4.
- New tumor event: New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 547 days; disease-specific survival: no event (censored), 547 days; progression-free interval: no event (censored), 547 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZG-A9M4-01A-11D-A41J-01): tumor purity 0.53, ploidy 3.52, whole-genome doublings 1.
